Somatic mutation profile of tumor specimen TCGA-G2-AA3F-01A (aliquot TCGA-G2-AA3F-01A-12D-A42E-08) from TCGA case TCGA-G2-AA3F, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 77.9 years (28,457 days).
Specimen TCGA-G2-AA3F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67108aea-feab-4d34-8a68-5f4180735ad5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-AA3F-10A (Blood Derived Normal), aliquot TCGA-G2-AA3F-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cef2c2be-f93e-42ee-b4f3-62930b07320f

The open-access MAF lists 158 somatic variants for this specimen: 120 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 34, Frame Shift Del 6, Frame Shift Ins 5, Nonsense Mutation 4, In Frame Del 3, Splice Site 3, Intron 2, RNA 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15088C>T p.R5030C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555185875, CM138453, COSV56417619; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455dup p.P153Afs*28 | Frame Shift Ins (INS) | VAF 14/51 reads (27%) | catalogued as rs730882019, COSV53468298, COSV99394349; ClinVar: pathogenic; called by pindel, varscan2
- ABI3 | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs761344907, COSV56799961; called by mutect2, varscan2
- ACSBG2 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV53124480; called by muse, mutect2, varscan2
- AFF2 | c.742G>C p.A248P | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.602); catalogued as COSV60664041; called by muse, mutect2, varscan2
- AGRN | c.2184G>C p.E728D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as COSV101039160; called by muse, mutect2
- AKAP9 | c.8545A>C p.T2849P (on ENST00000359028; = p.T2825P on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV62345020; called by muse, mutect2, varscan2
- ANKRD34B | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as COSV58613782, COSV58613848; called by muse, mutect2, varscan2
- AQP8 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 65/102 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs745351844, COSV54845111; called by muse, mutect2, varscan2
- ARF4 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV57715032; called by muse, mutect2, varscan2
- ARHGAP26 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV50828845; called by muse, mutect2, varscan2
- ARID1A | c.1655C>G p.S552* | Nonsense Mutation (SNP) | VAF 54/105 reads (51%) | catalogued as COSV100251083, COSV61372151, COSV61388437; called by muse, mutect2, varscan2
- ARL13B | c.1000A>T p.T334S (on ENST00000394222 / NM_001174150.2; = p.T227S on NM_144996.4) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV57398094; called by muse, varscan2
- ASAP1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.935); catalogued as COSV63048179; called by muse, mutect2, varscan2
- ASCC3 | c.5021G>A p.R1674H | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751357098, COSV64974838; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1313A>G p.D438G | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50055667; called by muse, mutect2, varscan2
- BMP1 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59244309; called by muse, mutect2, varscan2
- C19orf12 | c.34A>G p.M12V (on ENST00000392278 / NM_001031726.3; = p.M1? on NM_031448.6) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs560956421, COSV60364612; called by muse, mutect2, varscan2
- CACNA1B | c.6578C>A p.T2193K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs772964775, COSV99500446; called by muse, varscan2
- CD96 | c.1720G>C p.E574Q (on ENST00000283285 / NM_198196.3; = p.E558Q on NM_005816.5) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV51912523, COSV51916031; called by muse, mutect2, varscan2
- CFAP299 | c.448dup p.R150Kfs*17 | Frame Shift Ins (INS) | VAF 14/66 reads (21%) | catalogued as rs761800837; called by mutect2, varscan2
- CHD8 | c.2516G>T p.G839V (on ENST00000646647 / NM_001170629.2; = p.G560V on NM_020920.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67870457; called by muse, mutect2, varscan2
- CHRNA10 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV51704281; called by muse, mutect2, varscan2
- COL6A5 | c.6991A>C p.T2331P (on ENST00000312481; = p.T2327P on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV55200595; called by muse, mutect2, varscan2
- CUL2 | c.1305C>G p.Y435* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | catalogued as COSV101039325, COSV66079011; called by muse, mutect2, varscan2
- DCAF12L2 | c.637C>A p.R213S | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63581513, COSV63584245; called by muse, mutect2, varscan2
- DICER1 | c.2660C>G p.S887C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV58619341; called by muse, mutect2, varscan2
- DNAAF2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100023733, COSV53567860; called by muse, mutect2
- DYNC2H1 | c.9887A>G p.K3296R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as rs1223682733, COSV62093420; called by muse, mutect2, varscan2
- EFEMP1 | c.383C>G p.P128R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as COSV62615980; called by muse, mutect2, varscan2
- FAM90A1 | c.1100G>C p.R367T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs767813589, COSV56716052; called by mutect2, varscan2
- FBN2 | c.4301G>C p.C1434S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as CM950455, COSV52510870; called by muse, mutect2
- FLG | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs780339198, COSV64241437; called by muse, mutect2
- FOXA1 | c.1416del p.*473Sfs*11 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as COSV51644956; called by mutect2, pindel, varscan2
- GAD2 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.303); catalogued as rs1259318388, COSV52150482; called by muse, mutect2, varscan2
- GGT1 | c.1374G>A p.M458I | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99959421; called by muse, mutect2
- GLT8D1 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as COSV56477463; called by muse, mutect2, varscan2
- GYS1 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs971609889, COSV54402656; called by muse, mutect2, varscan2
- H4C3 | c.40G>C p.G14R | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100619679; called by muse, mutect2
- HERC2 | c.8062C>T p.H2688Y | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV55322246, COSV99877897; called by muse, mutect2, varscan2
- HSD17B12 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV53499204; called by muse, mutect2, varscan2
- HUNK | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV54227904; called by muse, mutect2, varscan2
- IKBKE | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV65625367; called by muse, mutect2, varscan2
- INSYN2A | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs772129249, COSV54738698, COSV54756207; called by muse, mutect2, varscan2
- INTS14 | c.1072G>T p.E358* (on ENST00000313182 / NM_001366360.2; = p.E279* on NM_001136043.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100500149; called by muse, mutect2, varscan2
- IPO11 | c.877C>G p.Q293E | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.035); catalogued as COSV57575926; called by muse, mutect2, varscan2
- KCNMA1 | c.2810C>T p.S937L (on ENST00000286628 / NM_001161352.2; = p.S879L on NM_002247.4) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV54245963; called by muse, mutect2, varscan2
- KRT28 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs150448547; called by muse, mutect2, varscan2
- LARP4B | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV60221342; called by muse, mutect2, varscan2
- MAP3K1 | c.1153-2A>T p.X385_splice | Splice Site (SNP) | VAF 14/60 reads (23%) | catalogued as COSV68123454; called by muse, mutect2, varscan2
- MDGA2 | c.2902C>T p.R968* (on ENST00000399232 / NM_001113498.2; = p.R670* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV100637639, COSV100637642; called by muse, mutect2, varscan2
- MGA | c.7596G>C p.K2532N (on ENST00000219905 / NM_001164273.1; = p.K2323N on NM_001080541.2) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV54953328, COSV54953834; called by muse, mutect2
- MGA | c.7993G>T p.D2665Y (on ENST00000219905 / NM_001164273.1; = p.D2456Y on NM_001080541.2) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV54953340; called by muse, mutect2, varscan2
- MGA | c.8280G>C p.E2760D (on ENST00000219905 / NM_001164273.1; = p.E2551D on NM_001080541.2) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54953350; called by muse, mutect2, varscan2
- MIS12 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50147345; called by muse, mutect2, varscan2
- MSLNL | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV99558892; called by muse, mutect2
- MYL5 | c.521G>C p.*174Sext*? | Nonstop Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as rs371278586, COSV59140250, COSV59141261; called by muse, mutect2, varscan2
- NASP | c.764G>C p.R255T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV63112970; called by muse, mutect2, varscan2
- NCAM2 | c.638T>C p.M213T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV53073243; called by muse, mutect2, varscan2
- NRXN1 | c.4001G>A p.R1334K | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV60497722; called by muse, mutect2, varscan2
- OR2K2 | c.266A>G p.Y89C (on ENST00000374428; = p.Y60C on NM_205859.2) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs953608258, COSV57016863; called by muse, mutect2, varscan2
- OR6N1 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV58648289, COSV58649017; called by muse, mutect2, varscan2
- PGR | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54800959; called by muse, mutect2, varscan2
- PIGA | c.778A>G p.I260V | Missense Mutation (SNP) | VAF 59/67 reads (88%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1255714003, COSV61237547; called by muse, mutect2, varscan2
- PIGB | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV51241654; called by muse, mutect2, varscan2
- PIGG | c.2825G>A p.R942H (on ENST00000453061 / NM_001127178.3; = p.R934H on NM_017733.4) | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755336453, COSV56317642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PMS1 | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.466); catalogued as COSV59716279; called by muse, mutect2, varscan2
- POGLUT3 | c.660G>C p.E220D | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.759); catalogued as COSV60212496; called by muse, mutect2, varscan2
- PRAMEF2 | c.245T>A p.L82Q | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53575258, COSV99535049; called by muse, mutect2, varscan2
- PRDX4 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV65018661; called by muse, mutect2, varscan2
- PRKCA | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV52583768; called by muse, mutect2, varscan2
- PRR5 | c.286A>T p.M96L (on ENST00000336985 / NM_181333.4; = p.M87L on NM_015366.4) | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); catalogued as COSV50060049; called by muse, mutect2, varscan2
- PRRC2A | c.6101T>G p.L2034R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99277776; called by muse, mutect2
- PTCHD3 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71256754; called by muse, mutect2, varscan2
- PUM2 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.149); catalogued as COSV57580336; called by muse, mutect2, varscan2
- RAPSN | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV54084410; called by muse, mutect2, varscan2
- RHOB | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV55355269, COSV55355916; called by muse, mutect2, varscan2
- RIN3 | c.250-1G>C p.X84_splice | Splice Site (SNP) | VAF 34/199 reads (17%) | catalogued as COSV53648018; called by muse, mutect2, varscan2
- RTN3 | c.313dup p.S105Kfs*50 (on ENST00000377819 / NM_001265589.2; = p.S86Kfs*50 on NM_201428.3) | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | catalogued as rs1325714702; called by mutect2, pindel, varscan2
- SF3B1 | c.2708A>C p.Q903P | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100136056, COSV59210642; called by muse, mutect2, varscan2
- SHMT1 | c.815-1G>A p.X272_splice | Splice Site (SNP) | VAF 21/97 reads (22%) | catalogued as rs902076480, COSV57397802, COSV57398762; called by muse, mutect2, varscan2
- SIK3 | c.3578T>A p.I1193K (on ENST00000445177 / NM_001366686.2; = p.I1151K on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV52613715; called by muse, mutect2, varscan2
- SLC35F6 | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV60426433; called by muse, mutect2, varscan2
- SLITRK5 | c.1753G>A p.V585I | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as COSV61522682; called by muse, mutect2, varscan2
- SMARCA2 | c.3484C>A p.R1162S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as CM149465, COSV61804750, COSV61807046; called by muse, mutect2, varscan2
- SNX14 | c.1319T>C p.F440S (on ENST00000314673 / NM_001350535.1; = p.F396S on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1317543681, COSV59011789; called by muse, mutect2, varscan2
- SNX31 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61262979; called by muse, mutect2
- SPEN | c.6640G>C p.E2214Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65361406; called by muse, mutect2, varscan2
- SPEN | c.7388G>C p.S2463T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV65361411; called by muse, mutect2, varscan2
- TAF2 | c.3008C>G p.A1003G | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV65418027; called by muse, mutect2, varscan2
- TANC2 | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV67334027; called by muse, mutect2, varscan2
- TBC1D1 | c.2689G>T p.A897S | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV54718429; called by muse, mutect2, varscan2
- TBPL1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV52783614; called by muse, mutect2, varscan2
- TBX18 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63736723, COSV63736909; called by muse, mutect2, varscan2
- TFDP1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs148175670, COSV100946077; called by muse, mutect2, varscan2
- TIMELESS | c.308A>C p.E103A | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV57511187; called by muse, mutect2, varscan2
- TMEFF2 | c.862T>A p.S288T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.134); catalogued as COSV55832199; called by muse, mutect2, varscan2
- TNFRSF1A | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99165145; called by muse, mutect2
- TSHZ2 | c.1201G>T p.V401F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61588597; called by muse, mutect2, varscan2
- UBE2F | c.173A>C p.D58A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56025753; called by muse, mutect2, varscan2
- UNC5B | c.638G>C p.R213P | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs531794055, COSV58974158, COSV58976872; called by muse, mutect2, varscan2
- WIPF2 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60273638; called by muse, mutect2, varscan2
- Z83844.2 | c.660G>C p.E220D | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV60928109; called by muse, mutect2, varscan2
- ZMIZ2 | c.1148G>A p.S383N | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV54807741; called by muse, mutect2, varscan2
- ZNF277 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.266); catalogued as COSV100702333, COSV62464166; called by muse, mutect2, varscan2
- ZNF418 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.38); catalogued as COSV68675824; called by muse, mutect2, varscan2
- ZNF502 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV56073255; called by muse, mutect2, varscan2
- ZNF700 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.949); catalogued as COSV54312244, COSV54315238, COSV54315294; called by muse, mutect2, varscan2
- ADGRG2 | c.505_510del p.S169_E170del (on ENST00000379869 / NM_001079858.3; = p.S166_E167del on NM_005756.4) | In Frame Del (DEL) | VAF 28/36 reads (78%) | called by mutect2, pindel*, varscan2*
- CEP170 | c.534del p.Q179Sfs*36 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- EXOC3 | c.793_796del p.A265Ifs*17 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- IGHV3-49 | c.355A>G p.R119G | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); called by muse, mutect2
- KANSL1 | c.2266dup p.A756Gfs*25 | Frame Shift Ins (INS) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- PLAT | c.570_573dup p.V192Lfs*4 | Frame Shift Ins (INS) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- SYNRG | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TOMM70 | c.1470_1472del p.Q491del | In Frame Del (DEL) | VAF 14/74 reads (19%) | called by pindel, varscan2
- VSIG2 | c.214_218del p.H72Nfs*15 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.689del p.P230Lfs*3 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.32_50del p.F11Yfs*63 | Frame Shift Del (DEL) | VAF 29/108 reads (27%) | called by mutect2, pindel, varscan2
- ZNF215 | c.1278_1286del p.Q426_L428del | In Frame Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- ABI3BP | c.738C>T p.I246= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV52535312; called by muse, mutect2, varscan2
- ADARB1 | c.1749G>A p.S583= (on ENST00000360697 / NM_001346687.2; = p.S543= on NM_001112.4) | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs372954828; called by muse, mutect2, varscan2
- ANP32A | c.129A>G p.E43= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV51189528; called by muse, mutect2, varscan2
- ARMC9 | c.279C>A p.A93= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV63020784, COSV63023148; called by muse, mutect2, varscan2
- ASH2L | c.153G>C p.P51= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV51699442; called by muse, mutect2, varscan2
- BIRC7 | c.699C>A p.P233= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs895643525, COSV53901069, COSV99416990; called by muse, mutect2, varscan2
- C19orf12 | c.33G>T p.T11= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV60364614; called by muse, mutect2, varscan2
- CCDC24 | c.201C>T p.P67= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV58843700; called by muse, mutect2, varscan2
- CNTNAP1 | c.2322G>A p.R774= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs1313110629, COSV52850286; called by muse, mutect2, varscan2
- EDIL3 | c.888C>T p.L296= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV56895371; called by muse, mutect2, varscan2
- EEPD1 | c.441C>T p.L147= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV54197300; called by muse, mutect2, varscan2
- FASTKD2 | c.1686C>T p.L562= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1349950025, COSV52698447; called by muse, mutect2, varscan2
- FBXL7 | c.504C>T p.R168= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs566331650, COSV61646192; called by muse, varscan2
- FRYL | c.48C>T p.V16= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV51946367; called by muse, mutect2, varscan2
- GLB1L2 | c.1869C>T p.F623= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs140543170, COSV56996746, COSV56997826; called by mutect2, varscan2
- HNRNPF | c.171T>G p.A57= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV61560942; called by muse, mutect2, varscan2
- MDC1 | c.5316G>A p.E1772= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV64524447; called by muse, mutect2, varscan2
- MFSD9 | c.498G>T p.P166= | Silent (SNP) | VAF 78/97 reads (80%) | catalogued as COSV51493515; called by muse, mutect2, varscan2
- MKI67 | c.3141G>A p.T1047= | Silent (SNP) | VAF 53/250 reads (21%) | catalogued as rs138983955; called by muse, mutect2, varscan2
- NCAPH | c.1503G>A p.Q501= | Silent (SNP) | VAF 27/358 reads (8%) | catalogued as rs1432166969, COSV53636285; called by muse, mutect2
- OLFM3 | c.960G>T p.G320= (on ENST00000338858 / NM_001288821.1; = p.G300= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV58798430; called by muse, mutect2, varscan2
- OR2T4 | c.465C>T p.Y155= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs764146748, COSV100822408, COSV63543926; called by muse, mutect2, varscan2
- PCDHGB2 | c.1083A>G p.P361= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs963780957, COSV53941947; called by muse, mutect2, varscan2
- PDE8A | c.2136G>A p.E712= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV59636865; called by muse, mutect2, varscan2
- POMK | c.807C>T p.H269= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as rs754174652, COSV58857228; called by muse, mutect2, varscan2
- RNF180 | c.639G>A p.Q213= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV56961759, COSV99684946; called by muse, mutect2, varscan2
- SHARPIN | c.1089A>G p.P363= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100010640; called by muse, mutect2, varscan2
- SORCS3 | c.3546C>T p.L1182= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100865686, COSV63819426; called by muse, mutect2
- SPEN | c.7602G>A p.L2534= | Silent (SNP) | VAF 37/166 reads (22%) | catalogued as COSV65358104, COSV65361415; called by muse, mutect2, varscan2
- TLK1 | c.504C>T p.I168= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as COSV62630128; called by muse, mutect2, varscan2
- TRPM1 | c.2604C>T p.I868= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs990801681, COSV56634049; called by muse, varscan2
- USP10 | c.1308C>T p.C436= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99551918; called by muse, mutect2
- XAGE2 | c.267G>A p.K89= | Silent (SNP) | VAF 96/111 reads (86%) | called by muse, mutect2, varscan2
- ZNF217 | c.1917C>G p.L639= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV56596662, COSV56601550; called by muse, mutect2, varscan2
- AL133373.3 | n.877C>T | RNA (SNP) | VAF 6/14 reads (43%) | catalogued as rs1210551829; called by mutect2, varscan2
- GBA3 | c.59-8545G>A | Intron (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- MRC1 | c.917-133dup | Intron (INS) | VAF 34/292 reads (12%) | called by mutect2, varscan2
- ZNF137P | n.1900C>G | RNA (SNP) | VAF 7/15 reads (47%) | catalogued as rs772153985, COSV60963388; called by muse, varscan2
